Gene-level copy-number profile of tumor specimen ALCH-B005-TTP1-A from ALCHEMIST case ALCH-B005, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,751 days).
Specimen ALCH-B005-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6ca71c94-14ec-4783-93a0-c6b1610fed32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B005-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,764 have no estimate.
https://portal.gdc.cancer.gov/files/03c4ea3f-d98c-4f4a-af9a-8fd7301242e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 20,578; copy number 2: 32,325; copy number 3: 3,808; copy number 4: 743; copy number 5: 553; copy number 6: 227; copy number 7: 494; copy number 11: 53; copy number 14: 46.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,449,689–1,497,848, 2 genes: ATAD3C, ATAD3B.
- chr3:75,415,070–75,580,199, 7 genes (within-gene range 0–2): ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr8:8,228,595–8,244,865, 2 genes: FAM86B3P, ALG1L13P.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr19:42,752,686–43,171,515, 11 genes (within-gene range 0–2): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,359 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,865,012–142,807,888, 22 genes, copy number 5 (within-gene range 3–5): HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1.
- chr3:150,202,174–151,761,339, 35 genes, copy number 6 (within-gene range 4–6): AC117386.1, LINC01213, U2, LINC01214, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2.
- chr3:151,759,747–151,762,011, 1 gene, copy number 6 (within-gene range 4–6): AC068647.1.
- chr3:152,800,434–198,123,232, 781 genes, copy number 5–7 (broad region; genes not listed).
- chr6:36,854,827–36,928,964, 2 genes, copy number 5: PPIL1, C6orf89.
- chr6:71,886,703–73,696,131, 37 genes, copy number 5 (within-gene range 4–5): RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1.
- chr6:85,155,667–85,678,932, 15 genes, copy number 6: AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B.
- chr7:63,011,463–64,150,721, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:65,075,023–67,362,950, 76 genes, copy number 6 (broad region; genes not listed).
- chr7:94,278,680–95,324,532, 18 genes, copy number 6: AC002074.1, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1.
- chr8:49,496,763–49,512,180, 1 gene, copy number 6: AC090155.2.
- chr9:39,355,669–39,508,885, 7 genes, copy number 14: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr9:39,734,670–39,741,193, 2 genes, copy number 5: RAB28P1, RBPJP5.
- chr11:69,072,915–69,162,440, 1 gene, copy number 14 (within-gene range 1–14): AP003071.5.
- chr11:69,103,493–73,931,114, 160 genes, copy number 6–14 (broad region; genes not listed).
- chr12:37,575,587–37,576,384, 1 gene, copy number 6: ZNF970P.
- chr12:42,238,447–48,025,469, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr12:71,754,863–71,927,248, 5 genes, copy number 5: RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:106,703,846–106,704,286, 1 gene, copy number 5: IGHV1-68.
- chr14:106,723,574–106,771,020, 3 genes, copy number 5: IGHV2-70D, IGHV1-69D, IGHV2-70.
- chr16:32,869,985–32,873,128, 1 gene, copy number 6: BCAP31P2.
- chr16:33,094,204–33,134,499, 3 genes, copy number 11 (within-gene range 2–11): HERC2P8, AC145350.4, AC145350.1.

Autosomal genes at a single copy (total copy number 1): 18,250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
